Somatic mutation profile of tumor specimen C3L-01106-01 (aliquot CPT0127540007) from CPTAC case C3L-01106, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 51.2 years (18,693 days).
Specimen C3L-01106-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80825b80-b6f6-4b3f-a7ed-4196745fcc23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01106-31 (Blood Derived Normal), aliquot CPT0128590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2a4a30e-110c-4a69-b567-ed97b2a55adf

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 7, Intron 5, Nonsense Mutation 3, Frame Shift Del 2, Translation Start Site 1, 3'UTR 1, Frame Shift Ins 1, 5'Flank 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.1639C>T p.R547W (on ENST00000359125 / NM_172107.4; = p.R519W on NM_004518.6) | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs796052650, CM131778, COSV60557310; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- VHL | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 159/363 reads (44%) | catalogued as rs5030802, CM951268, CM984688, COSV56544079; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AQP8 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54845228; called by muse, mutect2, varscan2
- BIN2 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs1161982744; called by muse, mutect2, varscan2
- DCN | c.765C>A p.N255K | Missense Mutation (SNP) | VAF 129/451 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50009530; called by muse, mutect2, varscan2
- DISP1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs776285881, COSV52654096; called by muse, mutect2
- DPYS | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60906723; called by muse, mutect2, varscan2
- ITPR2 | c.2463C>G p.D821E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as COSV67277029; called by muse, mutect2, varscan2
- LRP1B | c.5402G>A p.G1801E | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67233969, COSV67250560; called by muse, mutect2, varscan2
- MTOR | c.6414G>T p.L2138F | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63871087, COSV63876174; called by muse, mutect2, varscan2
- REL | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs1390363101; called by mutect2, varscan2
- SCARA5 | c.175A>T p.K59* | Nonsense Mutation (SNP) | VAF 68/225 reads (30%) | catalogued as COSV104401466; called by muse, mutect2, varscan2
- SLC19A1 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV60754808; called by muse, mutect2, varscan2
- THEMIS | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV64073644; called by muse, mutect2, varscan2
- AHNAK | c.16162G>C p.G5388R | Missense Mutation (SNP) | VAF 83/281 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD27 | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 105/386 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMC2 | c.472A>C p.T158P | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAN | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 111/310 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP128 | c.53G>C p.S18T | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CYP11B2 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 151/513 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCLK1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXL5 | c.1786A>T p.T596S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.084); called by muse, varscan2
- GFRA4 | c.889G>T p.A297S (on ENST00000319242 / NM_145762.3; = p.A267S on NM_022139.4) | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMC3 | c.2093G>T p.G698V | Missense Mutation (SNP) | VAF 155/549 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MACF1 | c.12440T>G p.V4147G (on ENST00000372915; = p.V2080G on NM_012090.5) | Missense Mutation (SNP) | VAF 82/245 reads (33%) | called by muse, mutect2, varscan2
- MAX | c.295+2del p.X99_splice | Splice Site (DEL) | VAF 176/525 reads (34%) | called by mutect2, pindel, varscan2
- MPP5 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 19/302 reads (6%) | called by muse, mutect2
- NDUFB3 | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NKX6-2 | c.282del p.A96Rfs*92 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- PIGW | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PLA2G4F | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 110/423 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- QPCT | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); called by muse, mutect2
- SEC14L6 | c.773T>A p.I258N | Missense Mutation (SNP) | VAF 93/266 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STARD8 | c.2279T>A p.M760K | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by muse, mutect2
- TRPM3 | c.1222dup p.T408Nfs*34 (on ENST00000357533 / NM_001366142.2; = p.T253Nfs*34 on NM_020952.6) | Frame Shift Ins (INS) | VAF 59/237 reads (25%) | called by mutect2, pindel, varscan2
- UBE3D | c.1103G>C p.S368T | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- VCPIP1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- YLPM1 | c.3125del p.G1042Afs*20 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- ZNF281 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 106/323 reads (33%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZSCAN9 | c.976A>T p.I326F | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- HEATR5A | c.3099A>G p.L1033= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1360508939; called by muse, mutect2
- MCCD1 | c.261G>A p.G87= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as rs1420241102; called by muse, mutect2, varscan2
- MXRA5 | c.6447G>A p.T2149= | Silent (SNP) | VAF 73/158 reads (46%) | catalogued as COSV54246387, COSV99477297; called by muse, mutect2, varscan2
- PPM1J | c.669G>A p.Q223= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as COSV58551352; called by muse, mutect2, varscan2
- PRR12 | c.2577C>G p.A859= (on ENST00000615927; = p.A1680= on NM_020719.3) | Silent (SNP) | VAF 48/196 reads (24%) | called by muse, mutect2, varscan2
- SVEP1 | c.10020A>T p.T3340= | Silent (SNP) | VAF 50/157 reads (32%) | called by muse, mutect2, varscan2
- ZNF747 | c.568C>T p.L190= | Silent (SNP) | VAF 163/648 reads (25%) | catalogued as rs1266245081; called by muse, mutect2, varscan2
- BCORL1 | c.4306-2767del | Intron (DEL) | VAF 158/429 reads (37%) | called by mutect2, pindel, varscan2
- CCDC180 | chr9:97307381 G>A | 5'Flank (SNP) | VAF 22/75 reads (29%) | catalogued as rs752056232; called by muse, mutect2, varscan2
- MMP11 | c.1076-370A>C | Intron (SNP) | VAF 60/190 reads (32%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92533C>G | Intron (SNP) | VAF 119/487 reads (24%) | called by muse, mutect2, varscan2
- MYO9A | c.2303-9T>C | Intron (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- NDUFB10 | chr16:1965247 C>G | 3'Flank (SNP) | VAF 96/280 reads (34%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.*122C>G | 3'UTR (SNP) | VAF 123/438 reads (28%) | called by muse, mutect2, varscan2
- TLN2 | c.-36-6972A>G | Intron (SNP) | VAF 68/291 reads (23%) | catalogued as rs1415382189; called by muse, mutect2, varscan2
